TCGA case TCGA-DX-AB2L — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Fibromatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/27a6bd26-4b57-4eee-be02-6b20f5b69e1e

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 35 years; Vital status: Alive.

Diagnoses (1)
1. Fibromyxosarcoma: ICD-O-3 morphology code: 8811/3; ICD-10 code: C49.2; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 35.5 years (12,974 days); Year of diagnosis: 2009; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis present: No; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 6.

Follow-up (2 entries)
- Days to follow up: 1,618 days (4.4 years); Disease response: Tumor Free.
- Days to follow up: 2,007 days (5.5 years); Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-AB2L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 560 mg.
  Slide TCGA-DX-AB2L-01A-03-TSC: Section location: Top; Percent tumor cells: 35; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 65; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-DX-AB2L-01A-02-TSB: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DX-AB2L-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-AB2L-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Myxofibrosarcoma; Margin status: Positive; Tumor total necrosis: 0% (no necrosis or no mention of necrosis); Disease multifocal indicator: No; Locoregional recurrence indicator: No; Metastatic disease confirmed: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Thigh/knee.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic length: 6.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.

GDC annotations on this case (curator notes; quoted as recorded):
- Item may not meet study protocol: TSS informed the BCR that, upon pathologist review of FFPE slide prior to shipment to BCR, this case has no tumor in the TCGA specimen. It is a re-resection specimen. The BCRs pathologists reviewed the TSS frozen top slide, the 3 BCR frozen top slides, and the 25 diagnostic FFPE slides from the initial resection. The initial resection contained myxofibrosarcoma. The frozen top slides of the TCGA tumor do not show any tumor, only reactive tissue.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,007 days; disease-specific survival: no event (censored), 2,007 days; progression-free interval: no event (censored), 2,007 days.
